Somatic mutation profile of tumor specimen TCGA-AA-3660-01A (aliquot TCGA-AA-3660-01A-01D-1719-10) from TCGA case TCGA-AA-3660, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 51.8 years (18,932 days).
Specimen TCGA-AA-3660-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 869c750e-495b-4121-b595-e6afe7cf7d49.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3660-11A (Solid Tissue Normal), aliquot TCGA-AA-3660-11A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/301cf700-dc0f-4ed2-aeb6-74953e5cc33c

The open-access MAF lists 131 somatic variants for this specimen: 108 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 21, Nonsense Mutation 11, Frame Shift Del 3, In Frame Del 3, Splice Region 1, Frame Shift Ins 1, Splice Site 1, Intron 1, In Frame Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4099C>T p.Q1367* | Nonsense Mutation (SNP) | VAF 33/111 reads (30%) | hotspot (GDC flag); catalogued as rs121913328, CM940072, COSV57323776, COSV57337799; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DCX | c.115C>T p.R39* | Nonsense Mutation (SNP) | VAF 83/297 reads (28%) | catalogued as rs587783519, CM980518, COSV57567701, COSV57571382; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DHODH | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.673); catalogued as rs267606768, CM100134, COSV54662605; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 131/162 reads (81%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 159/804 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 31/56 reads (55%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC013489.1 | c.703C>A p.Q235K | Missense Mutation (SNP) | VAF 64/168 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV51551894; called by muse, mutect2, varscan2
- ACSM4 | c.217G>T p.A73S | Missense Mutation (SNP) | VAF 71/96 reads (74%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV101257078; called by muse, mutect2, varscan2
- ACTR10 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.305); catalogued as COSV54298844; called by muse, mutect2, varscan2
- ARHGAP29 | c.1367T>G p.L456R | Missense Mutation (SNP) | VAF 90/254 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV53113233; called by muse, mutect2, varscan2
- ARHGEF1 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374342194, COSV61528238; called by muse, mutect2, varscan2
- ARID5B | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs963038555, COSV54422608; called by muse, mutect2, varscan2
- ATP1A4 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 64/193 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs201945772, COSV63626913; called by muse, mutect2, varscan2
- BICC1 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 61/175 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.058); catalogued as COSV54064529; called by muse, mutect2, varscan2
- BNC1 | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 106/302 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61757068; called by muse, mutect2, varscan2
- BRD1 | c.1627C>T p.R543C | Missense Mutation (SNP) | VAF 81/173 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as rs774744137, COSV53458599; called by muse, mutect2, varscan2
- C1orf159 | c.421G>C p.A141P (on ENST00000379339 / NM_001330306.2; = p.A105P on NM_017891.5) | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV53881560; called by muse, mutect2, varscan2
- CACNA1H | c.4214G>A p.R1405Q | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1295752798, COSV61987936; called by muse, mutect2, varscan2
- CADPS2 | c.1041C>A p.D347E | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV100462018; called by muse, mutect2
- CAPN15 | c.3160G>A p.A1054T | Missense Mutation (SNP) | VAF 108/347 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54837003; called by muse, mutect2, varscan2
- CCDC18 | c.2356G>A p.V786I (on ENST00000343253 / NM_001306076.1; = p.V787I on NM_206886.4) | Missense Mutation (SNP) | VAF 136/393 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs200030282, COSV58144492; called by muse, mutect2, varscan2
- CDCA2 | c.1391C>A p.S464* | Nonsense Mutation (SNP) | VAF 8/106 reads (8%) | catalogued as COSV100398806; called by muse, mutect2
- CERKL | c.1421G>T p.R474I (on ENST00000339098 / NM_001030311.2; = p.R448I on NM_201548.5) | Missense Mutation (SNP) | VAF 227/363 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV59207144, COSV59209014; called by muse, mutect2, varscan2
- CFAP43 | c.2338G>A p.D780N | Missense Mutation (SNP) | VAF 94/324 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs368404211; called by muse, mutect2, varscan2
- CFAP65 | c.1543G>C p.A515P | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99838288; called by muse, mutect2
- CHGA | c.602G>A p.G201E | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV53663551; called by muse, mutect2, varscan2
- CHL1 | c.2585C>T p.P862L (on ENST00000397491 / NM_001253387.1; = p.P878L on NM_006614.4) | Missense Mutation (SNP) | VAF 72/197 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.07); catalogued as COSV56596339, COSV99851999; called by muse, mutect2, varscan2
- CSDE1 | c.521G>A p.R174H (on ENST00000358528 / NM_001007553.3; = p.R143H on NM_007158.6) | Missense Mutation (SNP) | VAF 24/342 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1227337956, COSV99794580; called by muse, mutect2
- CWC22 | c.493T>A p.S165T | Missense Mutation (SNP) | VAF 71/247 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1385511117, COSV99844132; called by muse, mutect2, varscan2
- CX3CR1 | c.764C>T p.T255M | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as rs375338951; called by muse, mutect2
- DCAF12L2 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1229366218, COSV63580270, COSV63581169; called by muse, mutect2, varscan2
- DMD | c.7112C>A p.A2371E | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.306); catalogued as rs767961100, COSV58920567; called by muse, mutect2, varscan2
- DOCK1 | c.1273C>T p.R425* | Nonsense Mutation (SNP) | VAF 45/116 reads (39%) | catalogued as COSV54745043; called by muse, mutect2, varscan2
- EXOC1 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs200940249, COSV62119464; called by muse, mutect2, varscan2
- FAM110B | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 72/289 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64066096; called by muse, mutect2, varscan2
- FAM47C | c.2842G>T p.G948W | Missense Mutation (SNP) | VAF 79/207 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs782306470, COSV63723870; called by muse, mutect2, varscan2
- FAT4 | c.4684G>T p.E1562* | Nonsense Mutation (SNP) | VAF 33/117 reads (28%) | catalogued as COSV67895770; called by muse, mutect2, varscan2
- FREM1 | c.6245G>T p.C2082F | Missense Mutation (SNP) | VAF 81/133 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756563762, COSV66525380; called by muse, mutect2, varscan2
- GFM1 | c.463A>G p.T155A | Missense Mutation (SNP) | VAF 83/323 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV51833416; called by muse, mutect2, varscan2
- GFPT2 | c.1847G>A p.R616H | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.124); catalogued as rs778999391, COSV99517536; called by muse, mutect2, varscan2
- GIMAP7 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 69/113 reads (61%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs200815148, COSV57958459; called by muse, mutect2, varscan2
- GNAS | c.2054G>A p.R685H | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58338169; called by muse, mutect2, varscan2
- HELZ | c.4540C>T p.R1514W | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1437722879, COSV62379124; called by muse, mutect2, varscan2
- HNRNPDL | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 136/348 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs141595181; called by muse, mutect2, varscan2
- INSC | c.835G>C p.E279Q | Missense Mutation (SNP) | VAF 59/181 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV101089669, COSV65411256; called by muse, mutect2, varscan2
- KAT2A | c.2042G>A p.R681H | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs764849106, COSV52425614; called by muse, mutect2, varscan2
- KCNB2 | c.2035G>A p.D679N | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.438); catalogued as rs774872332, COSV73050942; called by muse, mutect2, varscan2
- KCNS2 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.615); catalogued as rs377211918; called by muse, mutect2, varscan2
- LMBR1L | c.1216C>T p.L406F | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV57268056; called by muse, mutect2, varscan2
- LRRC66 | c.1037G>A p.R346K | Missense Mutation (SNP) | VAF 159/431 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58634512; called by muse, mutect2, varscan2
- MAD1L1 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as rs776910007, COSV54247991; called by muse, mutect2, varscan2
- MCCC1 | c.96G>A p.W32* | Nonsense Mutation (SNP) | VAF 68/258 reads (26%) | catalogued as rs536755857, COSV55609517; called by muse, mutect2, varscan2
- METTL21C | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1409843748, COSV57432909; called by muse, mutect2
- MMD2 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 69/135 reads (51%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV68660954; called by muse, mutect2, varscan2
- MON1A | c.1627C>T p.R543C | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765586761, COSV56560293, COSV56561188; called by muse, mutect2, varscan2
- MROH6 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs747367163, COSV52786291; called by muse, mutect2, varscan2
- MYO1C | c.1993C>T p.R665C (on ENST00000648651 / NM_001080779.2; = p.R630C on NM_033375.5) | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770632413, COSV62999529; called by muse, mutect2, varscan2
- NCAM2 | c.1889A>G p.Y630C | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99522447; called by muse, mutect2, varscan2
- NCKAP1L | c.214C>A p.Q72K | Missense Mutation (SNP) | VAF 59/160 reads (37%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.973); catalogued as rs558387284, COSV53208229; called by muse, mutect2, varscan2
- NEXMIF | c.2695G>T p.E899* | Nonsense Mutation (SNP) | VAF 86/400 reads (22%) | catalogued as COSV50041754, COSV50045392; called by muse, mutect2, varscan2
- NPC1 | c.2152G>A p.E718K | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99341107; called by muse, varscan2
- OGG1 | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99844684; called by muse, mutect2
- OR10X1 | c.402G>T p.M134I | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV63767516; called by muse, mutect2, varscan2
- OR5I1 | c.533A>C p.H178P | Missense Mutation (SNP) | VAF 67/155 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV56887556; called by muse, mutect2, varscan2
- PABPC5 | c.980C>A p.S327* | Nonsense Mutation (SNP) | VAF 88/430 reads (20%) | catalogued as COSV100442238; called by muse, mutect2, varscan2
- PCDHA12 | c.2159C>T p.A720V | Missense Mutation (SNP) | VAF 107/340 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.021); catalogued as COSV56497066; called by muse, mutect2, varscan2
- PEX2 | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 24/456 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.976); catalogued as COSV100824743; called by muse, mutect2
- PGRMC1 | c.218T>G p.F73C | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54293037; called by muse, mutect2, varscan2
- PIAS1 | c.314C>A p.S105* | Nonsense Mutation (SNP) | VAF 71/304 reads (23%) | catalogued as COSV51033435; called by muse, mutect2, varscan2
- PIK3CG | c.516G>T p.E172D | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV63249575; called by muse, mutect2, varscan2
- PLEC | c.1727A>G p.E576G (on ENST00000322810 / NM_201380.4; = p.E466G on NM_000445.5) | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.849); catalogued as COSV100512674; called by muse, mutect2
- PLTP | c.1360G>A p.G454R | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51942769; called by muse, mutect2, varscan2
- PORCN | c.443C>T p.T148M | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs782273836, COSV58226682; called by muse, mutect2, varscan2
- RAPGEF6 | c.1444G>A p.V482I | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57248612; called by muse, mutect2, varscan2
- RBAK | c.1811_1813del p.F604del | In Frame Del (DEL) | VAF 38/85 reads (45%) | catalogued as rs763824734; called by pindel, varscan2
- RBM46 | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV55979494; called by muse, mutect2, varscan2
- RFTN1 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 78/178 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.207); catalogued as rs781778331, COSV61920252; called by muse, mutect2, varscan2
- RGS12 | c.2027C>T p.T676M | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs528303715, COSV58753422; called by muse, mutect2, varscan2
- RUVBL2 | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55485751; called by muse, mutect2, varscan2
- SBF1 | c.3788C>T p.T1263M | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1339877415, COSV62368191; called by muse, mutect2
- SEMG2 | c.1429C>T p.R477* | Nonsense Mutation (SNP) | VAF 30/264 reads (11%) | catalogued as rs546357756, COSV65647159; called by muse, mutect2, varscan2
- SF3B1 | c.46C>G p.R16G | Missense Mutation (SNP) | VAF 76/117 reads (65%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.018); catalogued as COSV59217658, COSV59226150; called by muse, mutect2, varscan2
- SLC27A6 | c.1408C>A p.Q470K | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV52485978, COSV99322508; called by muse, mutect2, varscan2
- SLC46A3 | c.579G>C p.E193D | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.243); catalogued as COSV99906204; called by muse, mutect2, varscan2
- SLC7A2 | c.1042G>A p.A348T (on ENST00000494857 / NM_001370338.1; = p.A388T on NM_003046.6) | Missense Mutation (SNP) | VAF 80/191 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs139867348; called by muse, mutect2, varscan2
- SNRPB | c.120G>T p.L40F | Missense Mutation (SNP) | VAF 137/179 reads (77%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.531); catalogued as COSV60015828; called by muse, mutect2, varscan2
- SNTG1 | c.64C>G p.Q22E | Missense Mutation (SNP) | VAF 86/328 reads (26%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV52451088, COSV52476532; called by mutect2, varscan2
- SPEG | c.5533G>A p.A1845T | Missense Mutation (SNP) | VAF 103/141 reads (73%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.642); catalogued as rs759067349, COSV56675331; called by muse, mutect2, varscan2
- SPON1 | c.2153G>A p.R718Q | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as rs782756338, COSV59963100; called by muse, mutect2, varscan2
- SSBP2 | c.282+1G>A p.X94_splice | Splice Site (SNP) | VAF 25/94 reads (27%) | catalogued as COSV57798978; called by muse, mutect2, varscan2
- SV2A | c.1545G>A p.K515= | Splice Region (SNP) | VAF 36/121 reads (30%) | catalogued as COSV100975091; called by muse, mutect2, varscan2
- TECTA | c.6061C>T p.R2021C | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1455568421, COSV50697242; called by muse, mutect2, varscan2
- TENM4 | c.6725G>A p.R2242H | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs756653480, COSV53638748; called by muse, mutect2, varscan2
- TMEM41A | c.161T>C p.L54P | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99956567; called by muse, mutect2
- TOMM22 | c.128C>T p.T43I | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); catalogued as COSV53265823; called by muse, mutect2, varscan2
- TRIM65 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs773403074, COSV53933506; called by muse, mutect2, varscan2
- TTN | c.2950G>T p.E984* (on ENST00000591111; = p.E938* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 57/234 reads (24%) | catalogued as COSV100604001, COSV60116882; called by muse, mutect2, varscan2
- ZNF516 | c.2822C>T p.A941V | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs777120802, COSV101487241; called by muse, mutect2, varscan2
- ZNF609 | c.2315G>A p.G772E | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); catalogued as COSV58585290; called by muse, mutect2, varscan2
- ZNF718 | c.464T>C p.F155S | Missense Mutation (SNP) | VAF 82/254 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV68140472; called by muse, mutect2, varscan2
- ACOX2 | c.675del p.S226Vfs*32 | Frame Shift Del (DEL) | VAF 50/151 reads (33%) | called by mutect2, pindel, varscan2
- ADGRG1 | c.656_657del p.V219Efs*66 | Frame Shift Del (DEL) | VAF 26/92 reads (28%) | called by pindel, varscan2
- AL035461.3 | c.2890_2901del p.S964_A967del | In Frame Del (DEL) | VAF 28/84 reads (33%) | called by mutect2, varscan2
- GNAT1 | c.264_268dup p.Q90Pfs*16 | Frame Shift Ins (INS) | VAF 35/121 reads (29%) | called by mutect2, pindel, varscan2
- IGHG3 | c.829C>G p.Q277E | Missense Mutation (SNP) | VAF 74/309 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- INHBA | c.775_776insGGA p.G258_K259insR | In Frame Ins (INS) | VAF 11/60 reads (18%) | called by pindel, varscan2
- PTDSS1 | c.110_112del p.F37del | In Frame Del (DEL) | VAF 94/528 reads (18%) | called by pindel, varscan2
- TCEA3 | c.921_922del p.F308Pfs*13 | Frame Shift Del (DEL) | VAF 68/252 reads (27%) | called by pindel, varscan2
- ACOT12 | c.930T>C p.D310= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as COSV100296855; called by mutect2, varscan2
- ANK2 | c.10017G>A p.A3339= | Silent (SNP) | VAF 45/110 reads (41%) | catalogued as rs774143296, COSV52154986; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARAP2 | c.4800C>T p.S1600= | Silent (SNP) | VAF 42/114 reads (37%) | catalogued as rs1478019288, COSV58282346, COSV58288421; called by muse, mutect2, varscan2
- C3 | c.4749G>A p.T1583= | Silent (SNP) | VAF 67/164 reads (41%) | catalogued as rs780979839, COSV55574926; called by muse, mutect2, varscan2
- CILP2 | c.1740C>T p.P580= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as COSV52274522; called by muse, mutect2, varscan2
- FAT3 | c.2274T>C p.N758= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as rs570286992, COSV53127396; called by muse, mutect2, varscan2
- KCNA4 | c.162C>T p.S54= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs749000246, COSV60252647, COSV60253432, COSV60255384; called by muse, mutect2, varscan2
- KIAA1522 | c.693C>T p.A231= (on ENST00000373480 / NM_001198972.2; = p.A290= on NM_020888.3) | Silent (SNP) | VAF 11/111 reads (10%) | catalogued as rs554356770; called by muse, mutect2, varscan2
- KLHL14 | c.1386G>A p.A462= | Silent (SNP) | VAF 47/86 reads (55%) | catalogued as rs145852832, COSV63833482; called by muse, mutect2, varscan2
- KRT33A | c.819C>T p.I273= | Silent (SNP) | VAF 70/230 reads (30%) | catalogued as rs531117731, COSV50365290; called by muse, mutect2, varscan2
- LAMC3 | c.4140G>A p.A1380= | Silent (SNP) | VAF 50/210 reads (24%) | catalogued as rs753818876, COSV62654622; called by muse, mutect2, varscan2
- NLRP3 | c.2203C>T p.L735= | Silent (SNP) | VAF 59/226 reads (26%) | catalogued as COSV60226377; called by muse, mutect2, varscan2
- OBSL1 | c.1809C>T p.H603= | Silent (SNP) | VAF 17/124 reads (14%) | catalogued as rs768657041, COSV54719117; called by muse, mutect2, varscan2
- PAPPA | c.4503G>A p.E1501= | Silent (SNP) | VAF 39/156 reads (25%) | catalogued as rs967306755, COSV100073532; called by muse, mutect2, varscan2
- PAPSS2 | c.540T>G p.S180= | Silent (SNP) | VAF 67/196 reads (34%) | catalogued as COSV63263747; called by muse, mutect2, varscan2
- SNAP91 | c.1374C>T p.A458= | Silent (SNP) | VAF 60/92 reads (65%) | catalogued as rs764376228, COSV52125304; called by muse, varscan2
- TBC1D1 | c.2463C>T p.H821= | Silent (SNP) | VAF 48/258 reads (19%) | catalogued as COSV99790916; called by muse, mutect2, varscan2
- TBX22 | c.936C>T p.G312= | Silent (SNP) | VAF 24/159 reads (15%) | catalogued as rs376686839, COSV64786596; ClinVar: likely benign; called by muse, mutect2, varscan2
- USH1G | c.729G>A p.S243= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as COSV58882303; called by muse, mutect2, varscan2
- WNT16 | c.141C>T p.C47= (on ENST00000222462 / NM_057168.2; = p.C37= on NM_016087.2) | Silent (SNP) | VAF 11/193 reads (6%) | catalogued as rs1422491093, COSV55976270; called by muse, mutect2
- ZNF592 | c.540C>T p.G180= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs370990128; called by muse, mutect2, varscan2
- KIR3DL2 | chr19:54847188 C>T | 5'Flank (SNP) | VAF 87/205 reads (42%) | called by muse, mutect2, varscan2
- RAC1 | c.226-1450C>T | Intron (SNP) | VAF 17/254 reads (7%) | catalogued as rs1034208534, COSV100640979; called by muse, mutect2
